Gene-level copy-number profile of tumor specimen TCGA-46-3765-01A from TCGA case TCGA-46-3765, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-46-3765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d0047ff5-06f8-4ef1-ad0e-c82a9fce8482.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-46-3765-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a871a5a-bf58-4483-be0d-b06279043713

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 69; copy number 2: 13,192; copy number 3: 9,366; copy number 4: 26,216; copy number 5: 4,673; copy number 6: 1,998; copy number 7: 1,189; copy number 8: 1,014; copy number 9: 313; copy number 10: 459; copy number 11: 653; copy number 12: 12; copy number 13: 146; copy number 14: 56; copy number 15: 72; copy number 16: 32; copy number 17: 46; copy number 19: 71; copy number 20: 65; copy number 22: 16; copy number 23: 39; copy number 31: 57; copy number 32: 5; copy number 41: 5; copy number 48: 7; copy number 58: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-46-3765-01A-01D-0978-01): tumor purity 0.36, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,089 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:120,013,077–122,887,691, 39 genes, copy number 9 (within-gene range 5–9): EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1.
- chr2:136,765,545–137,715,440, 3 genes, copy number 9 (within-gene range 6–9): THSD7B, RNA5SP105, Y_RNA.
- chr2:144,666,312–145,338,057, 7 genes, copy number 10: TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5.
- chr2:161,424,332–161,985,282, 1 gene, copy number 17 (within-gene range 4–17): SLC4A10.
- chr2:161,500,885–162,371,595, 16 genes, copy number 17: AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA.
- chr2:162,496,936–162,497,051, 1 gene, copy number 17: RNA5SP109.
- chr2:176,989,418–183,608,119, 107 genes, copy number 15–22 (within-gene range 8–22) (broad region; genes not listed).
- chr2:212,581,357–213,152,427, 8 genes, copy number 11 (within-gene range 2–11): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2.
- chr3:176,415,439–178,007,779, 22 genes, copy number 9 (within-gene range 8–9): LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr3:178,960,121–187,207,629, 212 genes, copy number 10–13 (broad region; genes not listed).
- chr3:188,107,072–198,222,513, 223 genes, copy number 9–10 (broad region; genes not listed).
- chr4:54,836,041–56,388,153, 40 genes, copy number 12–16: AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1.
- chr4:56,396,312–56,396,871, 1 gene, copy number 12: AC068620.2.
- chr5:3,357,264–18,236,196, 256 genes, copy number 10–41 (within-gene range 7–41) (broad region; genes not listed).
- chr5:26,880,597–40,431,491, 199 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr6:122,859,678–127,918,631, 52 genes, copy number 12–58: ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5.
- chr6:128,027,886–128,085,248, 1 gene, copy number 31 (within-gene range 2–31): PTPRK-AS1.
- chr7:18,086,949–19,002,416, 1 gene, copy number 11 (within-gene range 8–11): HDAC9.
- chr7:18,807,993–23,564,261, 74 genes, copy number 11 (broad region; genes not listed).
- chr7:63,011,463–69,430,923, 215 genes, copy number 11–20 (within-gene range 11–30) (broad region; genes not listed).
- chr8:35,672,195–39,284,917, 85 genes, copy number 14–19 (within-gene range 2–19) (broad region; genes not listed).
- chr9:33,104,082–36,830,456, 173 genes, copy number 10–17 (within-gene range 2–17) (broad region; genes not listed).
- chr9:36,856,555–36,864,308, 2 genes, copy number 10: AL450267.1, MIR4540.
- chr10:71,790,747–73,737,311, 76 genes, copy number 10 (broad region; genes not listed).
- chr15:83,654,088–84,039,842, 1 gene, copy number 11 (within-gene range 4–11): ADAMTSL3.
- chr15:83,824,863–86,116,747, 77 genes, copy number 11 (broad region; genes not listed).
- chr22:18,906,028–20,151,055, 73 genes, copy number 9 (broad region; genes not listed).
- chr22:20,917,407–22,371,120, 124 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 69. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
